Gene-level copy-number profile of tumor specimen TCGA-FT-A3EE-01A from TCGA case TCGA-FT-A3EE, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder neck; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 80.2 years (29,293 days).
Specimen TCGA-FT-A3EE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.19ec0099-87cc-4d2c-867b-c75a409bd277.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FT-A3EE-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/daea9296-ad3f-40ca-bad2-6fbf23eda84b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 1,117; copy number 2: 31,097; copy number 3: 19,506; copy number 4: 5,134; copy number 5: 1,136; copy number 6: 1,795; copy number 7: 27; copy number 12: 2; copy number 13: 5.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-FT-A3EE-01A-11D-A201-01): tumor purity 0.61, ploidy 2.67, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,965 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:38,814–95,003,843, 1,667 genes, copy number 5–6 (broad region; genes not listed).
- chr3:11,745–1,987,470, 20 genes, copy number 6: LINC01986, AC066595.1, CHL1-AS2, AC066595.2, CHL1, RNU6-1194P, RPS8P6, CHL1-AS1, AC087428.1, LINC01266, RPSAP32, AC090044.1, AC087430.1, RN7SL120P, CNTN6, CRB3P1, RPL23AP38, RPL23AP39, RPL21P17, AC018814.1.
- chr5:18,886,622–27,496,994, 82 genes, copy number 5 (broad region; genes not listed).
- chr6:63,193,072–63,397,106, 7 genes, copy number 12–13: AL450346.1, FKBP1C, SPTLC1P3, AL450346.2, LGSN, AL121949.3, AL121949.2.
- chr7:70,972–62,275,678, 1,079 genes, copy number 6 (broad region; genes not listed).
- chr10:57,304,479–58,289,586, 8 genes, copy number 5 (within-gene range 2–5): MIR3924, AL731534.1, AC006484.1, MRPS35P3, AC026884.1, IPMK, TPT1P10, CISD1.
- chr10:81,870,778–83,068,071, 7 genes, copy number 6: AL096706.1, NRG3, AC010157.2, AC010157.1, NRG3-AS1, RNU6-441P, RNU6-478P.
- chr13:22,040,972–25,017,903, 68 genes, copy number 5 (broad region; genes not listed).
- chr13:50,082,169–50,906,856, 1 gene, copy number 7 (within-gene range 4–7): DLEU1.
- chr13:50,361,410–51,767,709, 26 genes, copy number 7 (within-gene range 2–7): RPL34P26, AL158195.1, DLEU7, RNA5SP28, RNASEH2B-AS1, RNASEH2B, GUCY1B2, RNA5SP29, C13orf42, RPL5P31, AL157817.1, PRELID3BP2, FAM124A, SERPINE3, MIR5693, INTS6, INTS6-AS1, RPS4XP16, RN7SL320P, SNRPGP11, MIR4703, RNU6-65P, WDFY2, RNY1P6, RN7SL413P, ATP5PBP1.

Autosomal genes at a single copy (total copy number 1): 2. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
